CPTAC case C3N-00168 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2d1ffb7e-8600-4d11-8a65-f27558c3ecfb

Demographics
Sex at birth: male; Race: asian; Year of birth: 1969; Vital status: Alive; Country of birth: Vietnam.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 47.5 years (17,349 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G3; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 826 days (2.3 years); Progression or recurrence: no; Days to last follow up: 826 days (2.3 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 387 days (1.1 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 2.
- Days to follow up: 826 days (2.3 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 2.
- Days to follow up: 826 days (2.3 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 2.

Other clinical attributes
- Weight: 53 kg; Height: 168 cm; BMI: 18.78.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 5; Cigarettes per day: 5; Tobacco smoking onset year: 1996; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 26.

Biospecimens (7 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00168-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -2 days; Initial weight: 250 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00168-21: Section location: Pole; Percent tumor nuclei: 65; Percent necrosis: 5.
- Sample C3N-00168-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -2 days; Initial weight: 250 mg; Time between clamping and freezing: 22 minutes; Time between excision and freezing: 2 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00168-22: Section location: Pole; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3N-00168-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -2 days; Initial weight: 250 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00168-23: Section location: Pole; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-00168-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -2 days; Initial weight: 250 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00168-24: Section location: Pole; Percent tumor nuclei: 60; Percent necrosis: 0.
- Sample C3N-00168-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -2 days; Initial weight: 200 mg; Time between clamping and freezing: 24 minutes; Time between excision and freezing: 4 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00168-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 200 mg.
- Sample C3N-00168-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -2 days; Method of sample procurement: Blood Draw.
